Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4848, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4848-01A (Primary Tumor).

FINAL DIAGNOSIS

PART 1: LEFT KIDNEY, RADICAL NEPHRECTOMY –

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR AND GRANULAR CELL) TYPE WITH AREAS OF NECROSIS, FUHRMAN'S NUCLEAR GRADE 3/4, EXTENSIVELY INVOLVING THE LEFT KIDNEY (14 CM).
- B. CARCINOMA EXTENDS THROUGH RENAL CAPSULE AND FOCALLY INVOLVES PERIRENAL ADIPOSE TISSUE (SLIDE 1H) AND RENAL SINUS (SLIDE 1D).
- C. LARGE OCCLUSIVE CARCINOMATOUS THROMBUS IS PRESENT WITHIN THE RENAL VEIN IN THE RENAL HILUM (SLIDES 1C, 1D), BUT DOES NOT INVOLVE THE RENAL VEIN MARGIN.
- D. ALL SURGICAL RESECTION MARGINS, PROXIMAL URETER AND GEROTA'S FASCIA ARE BENIGN.
- E. NON-NEOPLASTIC KIDNEY WITH NO SIGNIFICANT HISTOLOGIC ABNORMALITY.
- F. PATHOLOGIC STAGE: T3b, NX, MX.
- G. HISTOLOGIC GRADE: G3-4 (see microscopic description).

PART 2: LEFT ADJACENT NODULE, EXCISION # 1

RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR AND GRANULAR CELL) TYPE, FUHRMAN'S NUCLEAR GRADE 3/4, SURROUNDED BY A THIN FIBROUS CAPSULE WITH ATTACHED ADIPOSE TISSUE PRESENT (2.5 CM), APPEARING COMPLETELY EXCISED IN THE PLANE OF SECTION.

Source: NCI Genomic Data Commons file 5b7e97df-2eb3-48b7-82d7-28ff8d5d6106 (TCGA-B0-4848.20899D62-BDA2-459B-98AC-F83D737137FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).